FM case AD5039 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Primary site: Other and unspecified urinary organs.
https://portal.gdc.cancer.gov/cases/e05e3826-2d3c-4105-b204-928bb09fcf13

Male, 50.3 years: diagnosis not reported by GDC of the urinary system; metastasis biopsied or resected from the ureter. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
